Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3447, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3447-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left Renal Mass

Source of Specimen(s):

- 1: Left kidney
- 2: Renal hilar lymph nodes

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled #1, "left kidney"

Gross Description: Received fresh labeled ", left kidney" is a 569 gram left nephrectomy having a moderate amount of attached perinephric fat. There is a 6.0 x 0.3 cm fragment of attached ureter having a lumen, 0.2 cm which is patent to the renal pelvis. The kidney itself is 12.0 x 6.0 x 5.5 cm in greatest dimension being covered by a red-purple capsule. It is bivalved to reveal red-purple firm renal parenchyma having a well-defined cortico-medullary junction. In the middle and lower poles there is a 10.0 x 5.5 x 4.5 cm mass having yellow to tan-brown soft cut surfaces. Representative sections are submitted in six blocks.

Designation of Sections: 1A- ureter and vascular margins, 1B-1E- tumor, 1F- random section kidney

Summary of Sections: multiple

Source of Tissue: 2. Labeled #2, "renal hilar lymph nodes"

Gross Description: Received fresh labeled ", renal hilar lymph nodes" are 1.5 x 1.0 x 0.4 cm of yellow-tan fibroadipose tissue. No lymph nodes are grossly identified. The tissue is entirely submitted in one block.

Designation of Sections: Block 2

Summary of Sections: undesignated-multiple

Final Diagnosis:

1. Left kidney, radical nephrectomy:
- Renal cell carcinoma, chromophobe type, Fuhrman nuclear grade 2 (10 cm), limited to kidney, carcinoma focally invades into but not through the capsule; see note.

[page 2 of 2]
- Ureter and vascular resection margins with no tumor seen.

Note: Immunohistochemistry stains show that the tumor cells are focally positive for CK7, positive for CD117 (membranous), with cytoplasmic stain for CD10, faintly stained with vimentin and focally positive for low molecular weight keratin (CAM5.2). Although the immunostaining pattern is somewhat mixed, the histologic appearance would be most consistent with a chromophobe type carcinoma.

2. Renal hilar lymph nodes, excision:

- Fibroadipose tissue, No tumor seen.
- No lymphoid tissue identified.

(pT2NxMx)

Source: NCI Genomic Data Commons file 9fd97e6f-cc46-41f7-80b4-f933b3fd6a1e (TCGA-AK-3447.E4C71BFF-680A-4631-95FA-CDD0CB58844C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).